Somatic mutation profile of tumor specimen TARGET-15-SJMPAL040033-09A.3 (aliquot TARGET-15-SJMPAL040033-09A.3-01D) from TARGET case TARGET-15-SJMPAL040033, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.4 years (5,242 days).
Specimen TARGET-15-SJMPAL040033-09A.3: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8d72ecb7-1a8a-4da7-927d-0df1625218a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL040033-14A.1 (Bone Marrow Normal), aliquot TARGET-15-SJMPAL040033-14A.1-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45fa33f7-830a-4831-bce0-57709bb61b62

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 12, Silent 3, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA1 | c.1328G>A p.R443K | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs199916575, COSV66069988; called by muse, mutect2, varscan2
- CFAP61 | c.1855C>T p.R619* | Nonsense Mutation (SNP) | VAF 26/52 reads (50%) | catalogued as COSV55618034, COSV55618947; called by muse, varscan2
- INSC | c.1688G>A p.R563Q | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs751225472; called by muse, varscan2
- LRRK2 | c.2443C>A p.P815T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.424); catalogued as rs1484372271; ClinVar: uncertain significance; called by muse, varscan2
- NDST1 | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as rs770142868; called by muse, mutect2, varscan2
- PLSCR4 | c.888C>A p.F296L | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61607453; called by muse, mutect2, varscan2
- SCML1 | c.643C>T p.R215W (on ENST00000380041 / NM_001037540.3; = p.R188W on NM_006746.6) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV101193977; called by muse, mutect2, varscan2
- ZNF469 | c.5521C>T p.R1841W (on ENST00000437464; = p.R1869W on NM_001367624.2) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1292024809, COSV101458687; called by muse, mutect2, varscan2
- ABCA7 | c.411C>A p.S137R | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITGAE | c.2754+1G>T p.X918_splice | Splice Site (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- PAPLN | c.1618C>A p.L540I (on ENST00000554301; = p.L513I on NM_173462.4) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2
- PHYHIP | c.982G>T p.V328L | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.854); called by muse, mutect2
- PRUNE2 | c.6780G>T p.Q2260H | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.014); called by muse, mutect2
- RGS22 | c.2784G>T p.Q928H | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FEM1C | c.1563G>A p.V521= | Silent (SNP) | VAF 13/31 reads (42%) | called by muse, mutect2, varscan2
- PGGHG | c.489C>A p.T163= | Silent (SNP) | VAF 3/17 reads (18%) | called by muse, mutect2
- RNF213 | c.5259C>A p.A1753= | Silent (SNP) | VAF 5/73 reads (7%) | called by muse, mutect2
